Somatic mutation profile of tumor specimen TCGA-24-1562-01A (aliquot TCGA-24-1562-01A-01W-0553-09) from TCGA case TCGA-24-1562, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 67.8 years (24,747 days).
Specimen TCGA-24-1562-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb452100-a909-4e3d-8ff8-d34b0be54db8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1562-10A (Blood Derived Normal), aliquot TCGA-24-1562-10A-01W-0553-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16c600ef-0741-4709-8190-cac3be315b2f

The open-access MAF lists 33 somatic variants for this specimen: 26 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 21, Silent 7, Frame Shift Ins 2, Nonsense Mutation 1, Splice Site 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.97-2A>T p.X33_splice | Splice Site (SNP) | VAF 179/247 reads (72%) | hotspot (GDC flag); catalogued as COSV52678373, COSV52848662, COSV53375861, COSV53887648; called by muse, mutect2, varscan2
- ABHD13 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 48/213 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV65534253; called by muse, mutect2, varscan2
- ALX1 | c.550A>G p.R184G | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100374541; called by muse, mutect2
- ANOS1 | c.1850A>G p.Y617C | Missense Mutation (SNP) | VAF 30/36 reads (83%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.907); catalogued as COSV99391319; called by muse, mutect2, varscan2
- CHEK2 | c.1166G>A p.R389H (on ENST00000382580 / NM_001005735.2; = p.R346H on NM_007194.4) | Missense Mutation (SNP) | VAF 35/46 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730881688, COSV60415236, COSV60418038; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUL7 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1561897257, COSV54812896; called by muse, mutect2, varscan2
- DPY19L4 | c.1583T>A p.I528N | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as COSV68962178; called by muse, mutect2, varscan2
- ESF1 | c.1207G>A p.V403I | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.057); catalogued as COSV52518773; called by muse, mutect2, varscan2
- FAT1 | c.6865G>A p.A2289T | Missense Mutation (SNP) | VAF 63/161 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV71671701; called by muse, mutect2, varscan2
- IPMK | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 66/189 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs766684585, COSV64243317, COSV64243598; called by muse, mutect2, varscan2
- KIR2DL3 | c.967C>T p.P323S | Missense Mutation (SNP) | VAF 409/903 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as COSV60895160; called by muse, mutect2, varscan2
- KLHL24 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 47/204 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as rs755654793, COSV54424414; called by muse, mutect2, varscan2
- LRRN2 | c.1292dup p.S432Kfs*75 | Frame Shift Ins (INS) | VAF 4/45 reads (9%) | catalogued as rs1186903618; called by pindel, varscan2
- NT5E | c.1027A>G p.I343V | Missense Mutation (SNP) | VAF 145/204 reads (71%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs941664377, COSV57627173; called by muse, mutect2, varscan2
- PKNOX2 | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.018); catalogued as COSV53540402, COSV53556292; called by muse, mutect2, varscan2
- PLCB4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as COSV53791864; called by muse, mutect2, varscan2
- PROKR2 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1042038054, COSV54085035; called by muse, mutect2, varscan2
- PSMC3 | c.1057G>T p.E353* | Nonsense Mutation (SNP) | VAF 16/32 reads (50%) | catalogued as COSV54080075; called by muse, mutect2, varscan2
- RSC1A1 | c.214C>G p.L72V | Missense Mutation (SNP) | VAF 165/359 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.054); catalogued as COSV60778883; called by muse, mutect2, varscan2
- TMEM43 | c.1171C>T p.R391W | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV53203511; called by muse, mutect2, varscan2
- TNPO2 | c.2128C>G p.L710V | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.395); catalogued as rs1408636107, COSV63507409, COSV63507459; called by muse, mutect2
- UBXN2B | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 83/262 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68308523; called by muse, mutect2, varscan2
- XPO6 | c.2240G>A p.R747H | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58963077; called by muse, mutect2
- ZNF267 | c.1679G>C p.S560T | Missense Mutation (SNP) | VAF 53/82 reads (65%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV56250307; called by muse, mutect2, varscan2
- NF1 | c.6285dup p.V2096Cfs*24 (on ENST00000358273 / NM_001042492.3; = p.V2075Cfs*24 on NM_000267.3) | Frame Shift Ins (INS) | VAF 39/66 reads (59%) | called by mutect2, pindel, varscan2
- SERPINA5 | c.1147G>A p.V383M | Missense Mutation (SNP) | VAF 178/412 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ALPK2 | c.3306G>A p.Q1102= | Silent (SNP) | VAF 143/213 reads (67%) | catalogued as COSV64489983, COSV64494760; called by muse, mutect2, varscan2
- DCN | c.288C>A p.I96= | Silent (SNP) | VAF 41/153 reads (27%) | catalogued as COSV50006010; called by muse, mutect2, varscan2
- FHOD3 | c.894C>A p.S298= | Silent (SNP) | VAF 54/70 reads (77%) | catalogued as COSV99942540, COSV99943553; called by muse, mutect2, varscan2
- PTPRO | c.1314C>T p.H438= | Silent (SNP) | VAF 21/31 reads (68%) | catalogued as rs140514339; called by muse, mutect2, varscan2
- PWWP3B | c.1596C>G p.T532= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as COSV61798158; called by muse, mutect2, varscan2
- SYCE1 | c.546A>T p.A182= (on ENST00000343131 / NM_001143764.3; = p.A146= on NM_130784.3) | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV100385947; called by muse, mutect2, varscan2
- VEZF1 | c.996C>T p.T332= | Silent (SNP) | VAF 41/57 reads (72%) | catalogued as COSV51967316; called by muse, mutect2, varscan2
